FM case AD11514 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/b582c47c-eb03-4850-88c6-99a64f674eb5

Female, 54.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the rectum; primary biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
